OHSU case 4343 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2142fcd1-f8c4-43cd-bdf5-cfa0aa11cec2

Demographics
Vital status: Dead.

Diagnoses (1)
1. Chronic myelomonocytic leukemia, NOS: ICD-O-3 morphology code: 9945/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.0 years (21,184 days); Days to last follow up: 318 days.

Biospecimens (1 sample)
- Sample 4753D: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
